Somatic mutation profile of tumor specimen 0DMIOH from CCDI case PBCAFX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 2.8 years (1,034 days).
Specimen 0DMIOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1def4dc-3b5d-480a-9a7a-477d8fc718bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMIPH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21b9ffd5-3b5c-466a-bb6c-98a4857c02ff

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZFP28 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 46/1258 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- APOL2 | c.*33G>T | 3'UTR (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- CCDC159 | c.689+42A>T | Intron (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 14/191 reads (7%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
